Somatic mutation profile of tumor specimen BA3206D (aliquot aq-BA3206D) from BEATAML1.0 case 2668, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.8 years (13,094 days).
Specimen BA3206D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 849c4265-5408-46d4-aff2-dc19ee849b0b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3360D (Solid Tissue Normal), aliquot aq-BA3360D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9c1778a-f2c7-47cc-8b34-bc166c2d97a8

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.2114C>T p.A705V (on ENST00000611781; = p.A649V on NM_052997.2) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs767521584, COSV64607238; called by muse, varscan2
- EPHA3 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 61/213 reads (29%) | catalogued as rs1453560937, COSV60703370, COSV60714910; called by muse, mutect2, varscan2
- TCTN2 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as rs761087301; called by muse, mutect2, varscan2
- GTF2I | c.2628dup p.S877* (on ENST00000573035 / NM_032999.4; = p.S836* on NM_001518.5) | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel
- KDM3B | c.4622A>G p.Y1541C | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PRPH | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PARD3 | c.3555C>T p.N1185= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs769589171; called by muse, mutect2, varscan2
- TTN | c.24621G>A p.G8207= (on ENST00000591111; = p.G7280= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/238 reads (31%) | called by muse, mutect2, varscan2
- MLIP | c.612+11927G>A | Intron (SNP) | VAF 112/377 reads (30%) | catalogued as COSV99229531; called by muse, mutect2, varscan2
